Somatic mutation profile of tumor specimen TCGA-FU-A770-01A (aliquot TCGA-FU-A770-01A-11D-A33O-09) from TCGA case TCGA-FU-A770, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, endocervical type; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IIIB; Tumor grade: G2; Age at diagnosis: 33.5 years (12,248 days).
Specimen TCGA-FU-A770-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 628710ed-543e-4e0f-9286-c01ef2c229e4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-FU-A770-10A (Blood Derived Normal), aliquot TCGA-FU-A770-10A-01D-A33O-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/63ba443c-463d-4219-984a-f497cdc3f2ea

The open-access MAF lists 51 somatic variants for this specimen: 38 protein-altering or splice-affecting, 12 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 31, Silent 12, Nonsense Mutation 3, Frame Shift Ins 2, Splice Region 1, Splice Site 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACACB | c.5716G>C p.E1906Q | Missense Mutation (SNP) | VAF 15/35 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58147108; called by muse, mutect2, varscan2
- ARHGAP35 | c.22G>C p.D8H | Missense Mutation (SNP) | VAF 26/63 reads (41%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.881); catalogued as COSV101351487, COSV68335835; called by muse, mutect2, varscan2
- ATMIN | c.1669C>T p.Q557* | Nonsense Mutation (SNP) | VAF 12/33 reads (36%) | catalogued as COSV55146433; called by muse, mutect2, varscan2
- BSN | c.11653G>A p.A3885T | Missense Mutation (SNP) | VAF 17/54 reads (31%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.022); catalogued as rs202222119, COSV56520503; called by muse, mutect2, varscan2
- C6 | c.1219C>T p.R407C | Missense Mutation (SNP) | VAF 27/83 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.912); catalogued as rs147449601, COSV54708576, COSV54712557; called by muse, mutect2, varscan2
- CA6 | c.662C>T p.T221M | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs750061032, COSV66263067; called by muse, mutect2, varscan2
- CASP14 | c.250G>A p.V84M | Missense Mutation (SNP) | VAF 15/48 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs746084490, COSV55666729; called by muse, mutect2, varscan2
- CERS3 | c.1088A>G p.D363G | Missense Mutation (SNP) | VAF 16/58 reads (28%) | SIFT tolerated (0.37); PolyPhen benign (0.102); catalogued as COSV52574945; called by muse, mutect2, varscan2
- COL20A1 | c.2770G>A p.E924K | Missense Mutation (SNP) | VAF 21/64 reads (33%) | SIFT tolerated (0.16); PolyPhen benign (0.288); catalogued as rs940514489, COSV58927694; called by muse, mutect2, varscan2
- COQ3 | c.108T>C p.V36= | Splice Region (SNP) | VAF 24/88 reads (27%) | catalogued as COSV54642085; called by muse, mutect2
- DPP10 | c.1387C>G p.R463G | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59730475; called by muse, mutect2, varscan2
- GABRG1 | c.782C>T p.T261I | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.776); catalogued as rs1000210963, COSV54962111; called by muse, mutect2, varscan2
- GPR50 | c.871G>A p.A291T | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.647); catalogued as COSV54442470; called by muse, mutect2, varscan2
- HSD17B4 | c.986C>T p.S329L (on ENST00000414835 / NM_001199291.3; = p.S304L on NM_000414.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 15/63 reads (24%) | SIFT tolerated (0.07); PolyPhen benign (0.038); catalogued as rs958986994, COSV56339289; called by muse, mutect2, varscan2
- JRKL | c.511G>A p.E171K | Missense Mutation (SNP) | VAF 27/59 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.925); catalogued as COSV53595589; called by muse, mutect2, varscan2
- KCNJ4 | c.43C>T p.R15W | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.781); catalogued as rs1381470248, COSV57858883; called by muse, mutect2, varscan2
- KMT2C | c.3874C>T p.R1292* | Nonsense Mutation (SNP) | VAF 27/106 reads (25%) | catalogued as rs1554526666, COSV51503916; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MAML1 | c.2974C>G p.L992V | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52988730, COSV52988865; called by muse, mutect2, varscan2
- NPDC1 | c.386-1G>A p.X129_splice | Splice Site (SNP) | VAF 17/44 reads (39%) | catalogued as COSV58665419; called by muse, mutect2, varscan2
- NXF3 | c.494C>T p.A165V | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.903); catalogued as COSV67705176; called by muse, mutect2, varscan2
- PKD2L1 | c.107G>A p.R36K | Missense Mutation (SNP) | VAF 32/99 reads (32%) | SIFT tolerated (0.67); PolyPhen benign (0); catalogued as rs746209620, COSV58399069; called by muse, mutect2, varscan2
- PLCB1 | c.2974C>A p.Q992K | Missense Mutation (SNP) | VAF 21/55 reads (38%) | SIFT tolerated (0.87); PolyPhen benign (0); catalogued as COSV62069372; called by muse, mutect2, varscan2
- POLD2 | c.599C>T p.S200F | Missense Mutation (SNP) | VAF 21/62 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56261420; called by muse, mutect2, varscan2
- POLQ | c.341C>T p.S114L | Missense Mutation (SNP) | VAF 14/83 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.752); catalogued as COSV51751436, COSV99953109; called by muse, mutect2, varscan2
- PRPF8 | c.5557C>T p.P1853S | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); catalogued as COSV59268000; called by muse, mutect2
- SCN8A | c.2737G>A p.E913K | Missense Mutation (SNP) | VAF 36/104 reads (35%) | SIFT tolerated (0.39); PolyPhen benign (0.058); catalogued as COSV61982007; called by muse, varscan2
- SCN8A | c.2836G>A p.E946K | Missense Mutation (SNP) | VAF 32/92 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61993413; called by muse, varscan2
- SERPINA3 | c.910G>A p.E304K | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT tolerated (0.9); PolyPhen benign (0); catalogued as COSV67587193; called by muse, mutect2
- SORCS2 | c.2058G>T p.K686N | Missense Mutation (SNP) | VAF 3/24 reads (13%) | SIFT tolerated (0.32); PolyPhen benign (0.441); catalogued as COSV61183717; called by muse, mutect2
- TAS2R7 | c.366G>A p.M122I | Missense Mutation (SNP) | VAF 18/52 reads (35%) | SIFT tolerated (0.09); PolyPhen benign (0.034); catalogued as COSV53690820; called by muse, mutect2, varscan2
- TRAFD1 | c.215A>G p.K72R | Missense Mutation (SNP) | VAF 14/31 reads (45%) | SIFT tolerated (0.09); PolyPhen benign (0.022); catalogued as COSV57506569; called by muse, mutect2, varscan2
- TSPYL2 | c.1106C>G p.S369* | Nonsense Mutation (SNP) | VAF 7/22 reads (32%) | catalogued as COSV60238345; called by muse, mutect2, varscan2
- TTN | c.102790G>A p.D34264N (on ENST00000591111; = p.D26840N on NM_003319.4) | Missense Mutation (SNP) | VAF 12/44 reads (27%) | PolyPhen probably damaging (0.964); catalogued as COSV60360796; called by muse, mutect2, varscan2
- UGT2B10 | c.1078G>A p.D360N | Missense Mutation (SNP) | VAF 44/157 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV55323757; called by muse, mutect2, varscan2
- UNC13B | c.4714G>A p.E1572K | Missense Mutation (SNP) | VAF 18/54 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.6); catalogued as COSV61470555; called by muse, mutect2, varscan2
- ZNF41 | c.1412A>G p.D471G | Missense Mutation (SNP) | VAF 18/65 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.075); catalogued as COSV57445283; called by muse, mutect2, varscan2
- KMT2C | c.12645dup p.D4216Rfs*24 | Frame Shift Ins (INS) | VAF 7/58 reads (12%) | called by mutect2, pindel, varscan2
- SPTBN5 | c.6898_6904dup p.G2302Vfs*12 | Frame Shift Ins (INS) | VAF 18/80 reads (23%) | called by mutect2, varscan2
- APLN | c.222C>A p.P74= | Silent (SNP) | VAF 30/97 reads (31%) | catalogued as COSV56742463; called by muse, mutect2, varscan2
- BCKDK | c.504C>G p.L168= | Silent (SNP) | VAF 12/27 reads (44%) | catalogued as COSV54894070, COSV99570646; called by muse, mutect2, varscan2
- KIF3B | c.1243C>A p.R415= | Silent (SNP) | VAF 24/78 reads (31%) | catalogued as rs763853584, COSV100996347, COSV65229437; called by muse, varscan2
- MESP2 | c.912C>T p.A304= | Silent (SNP) | VAF 24/79 reads (30%) | catalogued as COSV59093729; called by muse, mutect2, varscan2
- NT5C1B | c.1743C>A p.I581= (on ENST00000359846 / NM_001199086.2; = p.I521= on NM_033253.4) | Silent (SNP) | VAF 10/42 reads (24%) | catalogued as COSV100409725; called by muse, mutect2, varscan2
- OVCH1 | c.903G>A p.R301= | Silent (SNP) | VAF 47/160 reads (29%) | catalogued as COSV58968370; called by muse, mutect2, varscan2
- RBM4B | c.12G>C p.L4= | Silent (SNP) | VAF 15/42 reads (36%) | catalogued as COSV59498233; called by muse, mutect2, varscan2
- REV3L | c.5886T>C p.N1962= | Silent (SNP) | VAF 14/45 reads (31%) | catalogued as COSV62623681; called by muse, mutect2, varscan2
- RPP30 | c.45G>A p.L15= | Silent (SNP) | VAF 11/45 reads (24%) | catalogued as rs1564709079, COSV53298153; called by muse, mutect2, varscan2
- SLC25A12 | c.648C>T p.F216= | Silent (SNP) | VAF 19/65 reads (29%) | catalogued as COSV55537491; called by muse, mutect2, varscan2
- SLC45A1 | c.1827C>T p.I609= | Silent (SNP) | VAF 9/33 reads (27%) | catalogued as rs775010072, COSV57095377; called by muse, mutect2, varscan2
- SLF1 | c.2610C>T p.L870= | Silent (SNP) | VAF 18/57 reads (32%) | catalogued as rs975970733, COSV54373765; called by muse, mutect2, varscan2
- AP000769.3 | chr11:65504840 T>A | 5'Flank (SNP) | VAF 38/94 reads (40%) | called by muse, mutect2, varscan2
